FM case AD1334 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/8ca79e32-cb35-4701-84e6-3b88fd18c01e

Male, 51.1 years: Carcinosarcoma, NOS (ICD-O-3 8980/3) of the lung; primary biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
